Gene-level copy-number profile of tumor specimen C3N-03051-02 from CPTAC case C3N-03051, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 65.8 years (24,037 days).
Specimen C3N-03051-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e77ab0a5-c010-4e90-b4b1-58ab81947b25.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03051-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/36988423-ab0f-4e49-85b5-20c2b9dfb672

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 149; copy number 2: 15,563; copy number 3: 27,044; copy number 4: 7,955; copy number 5: 4,152; copy number 6: 2,157; copy number 7: 1,409; copy number 8: 483; copy number 9: 4.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:37,936,707–37,936,768, 1 gene (within-gene range 0–2): RNU7-124P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,896 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,171,471–198,123,232, 623 genes, copy number 7–8 (broad region; genes not listed).
- chr5:58,198–52,282,859, 705 genes, copy number 7 (broad region; genes not listed).
- chr8:118,620,498–145,066,685, 470 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr12:40,692,439–41,072,415, 1 gene, copy number 9 (within-gene range 4–9): CNTN1.
- chr12:40,978,744–41,932,592, 9 genes, copy number 7–9: AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1.
- chr20:33,655,701–33,720,319, 8 genes, copy number 8: AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4.
- chr20:34,516,414–36,746,090, 80 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 149. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
